Somatic mutation profile of tumor specimen MMRF_2426_1_BM_CD138pos (aliquot MMRF_2426_1_BM_CD138pos_T1_KHS5U_L11067) from MMRF case MMRF_2426, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,090 days).
Specimen MMRF_2426_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22761381-2ee4-4ccb-aba6-a096110438c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2426_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2426_1_PB_WBC_C2_KHS5U_L11068; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b0f1ec3-fa3e-4973-86eb-982102baace9

The open-access MAF lists 207 somatic variants for this specimen: 96 protein-altering or splice-affecting, 22 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, 3'UTR 42, Intron 23, Silent 22, 5'Flank 9, 5'UTR 7, Nonsense Mutation 7, RNA 6, Frame Shift Del 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 48/49 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as COSV62936796; called by muse, mutect2, varscan2
- ADAT3 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1196409855; called by muse, mutect2
- CCDC107 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV58396652; called by muse, mutect2, varscan2
- CGNL1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 108/509 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1412714858, COSV99848402; called by muse, mutect2, varscan2
- CNTN5 | c.1796C>G p.A599G | Missense Mutation (SNP) | VAF 96/313 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV54325063; called by muse, mutect2, varscan2
- DLG2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1296211671; called by muse, mutect2, varscan2
- DNAH12 | c.3233G>A p.R1078Q (on ENST00000351747; = p.R1101Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs778714312, COSV61063847; called by muse, mutect2, varscan2
- EPHA1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs777199962; called by muse, mutect2, varscan2
- HSPG2 | c.6352C>T p.R2118C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750419410; called by muse, mutect2, varscan2
- IGKV4-1 | c.162C>G p.N54K | Missense Mutation (SNP) | VAF 57/60 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as rs377562661; called by muse, varscan2
- IGKV4-1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs749276071; called by muse, mutect2, varscan2
- KIF21B | c.4391C>T p.T1464M (on ENST00000422435 / NM_001252100.2; = p.T1451M on NM_017596.4) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.488); catalogued as rs146916477; called by muse, mutect2, varscan2
- LGALS3BP | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs769208470; called by muse, mutect2, varscan2
- LINGO1 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 215/436 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs927185942; called by muse, mutect2, varscan2
- LRP3 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs1192833824; called by muse, mutect2, varscan2
- MARCKS | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.048); catalogued as COSV64042698; called by muse, mutect2
- MPIG6B | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs777620756; called by muse, mutect2, varscan2
- MSL2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 124/397 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV99387611; called by muse, mutect2, varscan2
- MUC5AC | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0); catalogued as COSV100650732; called by muse, mutect2
- MYOF | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372498089; called by muse, mutect2, varscan2
- NDOR1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs770565072; called by muse, mutect2, varscan2
- NEK9 | c.2365G>C p.E789Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.012); catalogued as rs1311339824; called by muse, mutect2, varscan2
- NMB | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436154413; called by muse, mutect2, varscan2
- NTRK3 | c.1348T>A p.F450I | Missense Mutation (SNP) | VAF 20/507 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV58123658; called by muse, mutect2
- OR51B6 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV66512801; called by muse, mutect2
- PMS1 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs576285843, COSV59718819; called by muse, mutect2, varscan2
- RBP3 | c.2488G>T p.A830S | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs782226632; called by muse, mutect2, varscan2
- RP1 | c.4982C>G p.S1661C | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV104377563, COSV55112671; called by muse, mutect2, varscan2
- SCAF4 | c.2506C>T p.P836S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs747076602; called by muse, mutect2, varscan2
- SCG2 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV59539930; called by muse, mutect2
- SCG3 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV55021036; called by muse, mutect2
- SPATA9 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99174154; called by muse, mutect2
- THUMPD2 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV53187616; called by muse, mutect2, varscan2
- TRIM3 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs751113447; called by muse, mutect2, varscan2
- ZFR2 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs1279681859, COSV53596077; called by muse, mutect2, varscan2
- ZNF229 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs781088110; called by muse, mutect2, varscan2
- ZNF583 | c.1610A>G p.H537R | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs762788438; called by muse, mutect2
- A2ML1 | c.2501T>A p.L834Q | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2
- ADAMTS12 | c.4205C>A p.P1402Q | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARAP2 | c.2449T>A p.C817S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARAP2 | c.1241A>C p.E414A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2
- ARHGEF10 | c.4056G>T p.Q1352H (on ENST00000398564; = p.Q1327H on NM_014629.4) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- CALN1 | c.513C>A p.C171* (on ENST00000329008 / NM_001017440.3; = p.C213* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CCDC88C | c.2834T>A p.L945Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CFAP46 | c.2120+1G>T p.X707_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- CTC1 | c.3332T>G p.V1111G | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- CYP26B1 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF5 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DDX42 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- DEFB115 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FARP1 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- FBXL20 | c.89A>T p.K30I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRSF1 | c.1245A>C p.Q415H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- H3C7 | c.260del p.S87Tfs*4 | Frame Shift Del (DEL) | VAF 86/196 reads (44%) | called by mutect2, varscan2
- HNRNPU | c.1948A>T p.N650Y (on ENST00000283179; = p.N712Y on NM_004501.3) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ICAM1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- IGKV4-1 | c.207_219del p.P70Ffs*? | Frame Shift Del (DEL) | VAF 40/50 reads (80%) | called by pindel, varscan2
- JCAD | c.3373C>T p.Q1125* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- KANK1 | c.920A>C p.N307T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM3B | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- KMT2B | c.7583C>A p.A2528D | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LDB2 | c.57G>C p.R19S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MAML2 | c.2697G>T p.L899F | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2
- MEPCE | c.1758G>T p.W586C | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MSL3 | c.1522T>A p.C508S (on ENST00000312196 / NM_078629.4; = p.C342S on NM_006800.4) | Missense Mutation (SNP) | VAF 67/69 reads (97%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTUS2 | c.1814C>A p.S605Y | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYO10 | c.4084C>A p.L1362M | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2
- MYPOP | c.1163C>G p.P388R | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NKAPD1 | c.390T>G p.I130M (on ENST00000280352 / NM_001082970.2; = p.I131M on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.299); called by muse, mutect2
- OR5V1 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR7A10 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PCDH8 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PNLDC1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PTPRB | c.5770T>A p.L1924I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- PTPRB | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF17 | c.1291T>A p.Y431N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF19A | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RRH | c.422dup p.Y141* | Nonsense Mutation (INS) | VAF 91/227 reads (40%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SORCS2 | c.2872C>G p.Q958E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN5 | c.9938C>A p.A3313D | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SRGAP3 | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 123/218 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- STC1 | c.423C>A p.N141K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TACR3 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- TGFB2 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TIGD3 | c.1407C>A p.C469* | Nonsense Mutation (SNP) | VAF 14/335 reads (4%) | called by muse, mutect2
- TRABD2A | c.1343T>C p.V448A (on ENST00000409520 / NM_001277053.2; = p.V399A on NM_001080824.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- TRIM9 | c.221C>A p.A74E | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TTN | c.68279C>A p.A22760D (on ENST00000591111; = p.A15336D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/146 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- WAPL | c.1591C>A p.Q531K | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZBTB11 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB46 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF318 | c.2432C>G p.S811* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- ZNF462 | c.4097C>A p.A1366D | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZP3 | c.162G>T p.M54I (on ENST00000394857 / NM_001110354.2; = p.M3I on NM_007155.6) | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ABCC8 | c.888G>T p.G296= | Silent (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- ADCY6 | c.1323C>T p.A441= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as rs376220809; called by muse, mutect2, varscan2
- ADGRG1 | c.1605C>A p.A535= | Silent (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- ANKFY1 | c.3381T>G p.R1127= (on ENST00000341657 / NM_001330063.2; = p.R1128= on NM_016376.5) | Silent (SNP) | VAF 43/44 reads (98%) | called by muse, mutect2, varscan2
- APOB | c.7269G>A p.L2423= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- ATG7 | c.129T>C p.A43= | Silent (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- BCL11B | c.2298C>A p.G766= (on ENST00000357195 / NM_001282237.2; = p.G695= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CLEC4E | c.462C>T p.D154= | Silent (SNP) | VAF 85/183 reads (46%) | catalogued as rs375515544; called by muse, mutect2, varscan2
- DHX34 | c.366C>T p.G122= | Silent (SNP) | VAF 38/575 reads (7%) | called by muse, mutect2
- KCNH3 | c.2955C>T p.S985= | Silent (SNP) | VAF 82/163 reads (50%) | called by muse, mutect2, varscan2
- KLHL26 | c.1476G>T p.A492= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs1424912531, COSV56318649; called by muse, mutect2, varscan2
- LY75 | c.4857G>A p.V1619= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs114074602; called by muse, mutect2, varscan2
- NEB | c.14650T>C p.L4884= | Silent (SNP) | VAF 85/180 reads (47%) | catalogued as rs1334709136, COSV99425514; called by muse, mutect2, varscan2
- OR56A1 | c.753T>A p.I251= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- OR5L1 | c.351G>A p.V117= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV61732886; called by muse, mutect2
- PTPRE | c.1197C>T p.D399= | Silent (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- RHPN2 | c.555C>T p.F185= | Silent (SNP) | VAF 11/214 reads (5%) | catalogued as COSV54274512; called by muse, mutect2
- TENM2 | c.8127C>G p.A2709= (on ENST00000518659 / NM_001122679.2; = p.A2470= on NM_001080428.3) | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- TMC6 | c.1446C>A p.L482= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- UNC13C | c.4569C>A p.T1523= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV52854323; called by muse, mutect2, varscan2
- VKORC1 | c.408C>T p.I136= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs1396849650; called by muse, mutect2
- ZNF341 | c.1368C>T p.T456= (on ENST00000375200 / NM_001282935.1; = p.T449= on NM_032819.4) | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs1027341016; called by muse, mutect2
- AADAC | chr3:151814099 A>G | 5'Flank (SNP) | VAF 42/604 reads (7%) | called by muse, mutect2
- AC053481.2 | n.636G>A | RNA (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2
- ACTC1 | c.991-82del | Intron (DEL) | VAF 63/132 reads (48%) | catalogued as rs1231427105; called by mutect2, varscan2
- ANXA2 | c.*69A>G | 3'UTR (SNP) | VAF 60/457 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504879 del AT | 5'Flank (DEL) | VAF 136/406 reads (33%) | called by mutect2, varscan2
- ARNT2 | c.*3921C>A | 3'UTR (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- ATG7 | c.*1908dup | 3'UTR (INS) | VAF 28/104 reads (27%) | catalogued as rs1314148686; called by mutect2, pindel, varscan2
- ATR | c.6687+119C>A | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs193023149; called by muse, varscan2
- B4GALT6 | chr18:31622608 A>C | 3'Flank (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- BRMS1L | chr14:35826260 G>T | 5'Flank (SNP) | VAF 43/183 reads (23%) | called by muse, mutect2, varscan2
- C12orf43 | c.*2031G>A | 3'UTR (SNP) | VAF 49/114 reads (43%) | catalogued as rs1399553089; called by muse, mutect2, varscan2
- C22orf42 | c.*522C>T | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- C5orf58 | chr5:170232681 T>A | 5'Flank (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- CD7 | c.612+29A>G | Intron (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- CDC42SE2 | c.*2180C>T | 3'UTR (SNP) | VAF 49/160 reads (31%) | called by muse, mutect2, varscan2
- CDKN3 | chr14:54396874 C>A | 5'Flank (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CHFR | c.*413A>G | 3'UTR (SNP) | VAF 48/120 reads (40%) | catalogued as rs1053774837; called by muse, varscan2
- CKMT1A | c.*93C>A | 3'UTR (SNP) | VAF 48/1180 reads (4%) | called by muse, mutect2
- COL4A1 | c.4462+74C>T | Intron (SNP) | VAF 29/46 reads (63%) | catalogued as rs185711350; called by muse, mutect2, varscan2
- CXCL9 | c.*1378C>T | 3'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- DACT2 | c.*156T>A | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- DCX | c.*420T>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+1234G>T | Intron (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- DHRS7 | c.286+82G>C | Intron (SNP) | VAF 31/48 reads (65%) | called by mutect2, varscan2
- DNAH5 | c.*329C>T | 3'UTR (SNP) | VAF 9/89 reads (10%) | catalogued as rs1025381931; called by muse, mutect2
- ESRRB | c.1297-91C>T | Intron (SNP) | VAF 16/22 reads (73%) | catalogued as rs569302188; called by muse, mutect2
- FBXL21P | n.1237G>C | RNA (SNP) | VAF 38/137 reads (28%) | catalogued as COSV51809620; called by muse, mutect2, varscan2
- FCAR | c.*358T>C | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by mutect2, varscan2
- FOXL2NB | c.*2034C>T | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- GNGT2 | chr17:49202833 G>A | 3'Flank (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- GOLGA1 | c.-31G>A | 5'UTR (SNP) | VAF 82/176 reads (47%) | catalogued as rs768941334; called by muse, mutect2, varscan2
- IL17RD | c.*3140G>A | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- JAZF1-AS1 | n.685C>A | RNA (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- KANK3 | c.1936+17G>T | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- KAT2B | c.*432_*437del | 3'UTR (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- KIF13A | c.146+36101G>C | Intron (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- KIF23 | c.2380-991A>G | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- LMNB1 | c.-171T>G | 5'UTR (SNP) | VAF 42/68 reads (62%) | called by muse, varscan2
- LMNB1 | c.-170A>T | 5'UTR (SNP) | VAF 42/69 reads (61%) | called by muse, varscan2
- LRRC28 | c.168+3119T>C | Intron (SNP) | VAF 26/684 reads (4%) | called by muse, mutect2
- LRRC52 | c.-103C>A | 5'UTR (SNP) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- LSAMP | c.*103G>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- MAGT1 | chrX:77895536 C>T | 5'Flank (SNP) | VAF 5/38 reads (13%) | catalogued as rs1212649323; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851126 T>G | 5'Flank (SNP) | VAF 32/264 reads (12%) | catalogued as rs569234583; called by muse, varscan2
- MLPH | c.1540-1078C>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- MMP16 | c.*3513T>C | 3'UTR (SNP) | VAF 65/126 reads (52%) | called by muse, varscan2
- NFIB | c.*1927_*1943delinsATAATGTATGCTTT | 3'UTR (DEL) | VAF 10/95 reads (11%) | called by pindel, varscan2*
- NOX5 | c.*2036G>A | 3'UTR (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- NRXN1 | c.*771C>T | 3'UTR (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- NT5C3A | c.*6C>A | 3'UTR (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- OSBPL10 | c.2250+874G>C | Intron (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- PACSIN1 | c.*1384G>T | 3'UTR (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- PALLD | c.1501+8803C>T | Intron (SNP) | VAF 42/225 reads (19%) | called by muse, mutect2, varscan2
- PARD3B | c.*3444C>T | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- PCP4 | c.*21C>T | 3'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- PIAS4 | c.*125T>C | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PLEKHG6 | c.138+385T>A | Intron (SNP) | VAF 32/74 reads (43%) | catalogued as rs955040736; called by muse, mutect2, varscan2
- PRIMA1 | c.*166G>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- PRKG1 | c.-95C>A | 5'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- PTPRN | chr2:219309415 T>C | 5'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- RDH10 | c.*1581T>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | catalogued as rs889138477; called by muse, mutect2, varscan2
- RHPN2P1 | n.1017C>T | RNA (SNP) | VAF 64/654 reads (10%) | called by muse, varscan2
- RNF112 | c.588+65C>T | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RSL24D1 | c.*265T>A | 3'UTR (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- SDK2 | c.*3996G>C | 3'UTR (SNP) | VAF 88/149 reads (59%) | called by muse, mutect2, varscan2
- SDK2 | c.*3762G>C | 3'UTR (SNP) | VAF 82/141 reads (58%) | called by muse, varscan2
- SERF2 | chr15:43792232 C>G | 5'Flank (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- SGCE | c.498+125dup | Intron (INS) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- SLC36A2 | c.843+785A>G | Intron (SNP) | VAF 113/175 reads (65%) | called by muse, mutect2, varscan2
- SOX11 | c.*2313G>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100430881; called by muse, mutect2, varscan2
- SUSD5 | c.*130T>C | 3'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- THSD4 | c.*5977A>G | 3'UTR (SNP) | VAF 72/169 reads (43%) | catalogued as rs1464321120; called by muse, mutect2, varscan2
- TM4SF18 | c.267+88A>G | Intron (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- TMEFF2 | c.*1189T>A | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- TMEM196 | c.*1431A>T | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-231dup | 5'UTR (INS) | VAF 44/116 reads (38%) | called by mutect2, varscan2
- TNFRSF9 | c.*61C>G | 3'UTR (SNP) | VAF 28/761 reads (4%) | called by muse, mutect2
- TNPO2 | c.-13-163G>A | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- TNRC6B | c.*4838A>G | 3'UTR (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- TRIM7 | c.*132G>T | 3'UTR (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7405C>T | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- TXNDC5 | c.*963_*964del | 3'UTR (DEL) | VAF 42/109 reads (39%) | catalogued as rs1456137494; called by mutect2, pindel, varscan2
- TYRP1 | c.*1005T>C | 3'UTR (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- URGCP | c.202+494A>T | Intron (SNP) | VAF 32/428 reads (7%) | called by muse, mutect2
- VASH2 | c.365+46C>A | Intron (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- ZBTB42 | c.*1480A>C | 3'UTR (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- ZNF561-AS1 | n.1245G>T | RNA (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- ZNF561-AS1 | n.1246A>T | RNA (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- ZNF703 | c.-64G>T | 5'UTR (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
